Somatic mutation profile of tumor specimen TCGA-3A-A9I5-01A (aliquot TCGA-3A-A9I5-01A-11D-A38G-08) from TCGA case TCGA-3A-A9I5, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; Tumor grade: G1; Age at diagnosis: 58.0 years (21,175 days).
Specimen TCGA-3A-A9I5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4513939f-a3bf-4263-8891-f92bc637a4ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9I5-10A (Blood Derived Normal), aliquot TCGA-3A-A9I5-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de377011-9e61-4e2f-94ce-58b7b287d6fa

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 21, Silent 4, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs369968960; called by muse, mutect2, varscan2
- COG6 | c.1551C>A p.F517L | Missense Mutation (SNP) | VAF 58/475 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100743274; called by muse, mutect2, varscan2
- DST | c.8843C>T p.S2948L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1563123256, COSV99759137; called by muse, mutect2, varscan2
- DST | c.8842T>A p.S2948T | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as COSV99759139; called by muse, mutect2, varscan2
- EGF | c.2638G>A p.V880M | Missense Mutation (SNP) | VAF 142/747 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); catalogued as COSV99491293; called by muse, mutect2, varscan2
- IFT88 | c.1366A>G p.R456G (on ENST00000319980 / NM_001318493.2; = p.R447G on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/649 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV60675151; called by muse, mutect2, varscan2
- IRF2 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204790269, COSV101165882; called by muse, mutect2, varscan2
- KBTBD2 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 109/733 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100406571; called by muse, mutect2, varscan2
- KCNH4 | c.1675G>T p.A559S | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99237773; called by muse, mutect2, varscan2
- KIF27 | c.2338A>T p.K780* | Nonsense Mutation (SNP) | VAF 28/612 reads (5%) | catalogued as COSV99927232; called by muse, mutect2
- KLK15 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs1206224835, COSV100032573, COSV56826168; called by muse, mutect2, varscan2
- LATS1 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 88/613 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1034620976, COSV53585897; called by muse, mutect2, varscan2
- MEGF8 | c.4516C>T p.R1506C (on ENST00000251268 / NM_001271938.2; = p.R1439C on NM_001410.3) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs142361779; called by muse, varscan2
- MUC17 | c.5070del p.P1691Lfs*2 | Frame Shift Del (DEL) | VAF 183/1343 reads (14%) | catalogued as COSV60307671; called by mutect2, pindel, varscan2
- NIBAN1 | c.2027T>A p.L676H | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.35); catalogued as COSV100836559; called by muse, mutect2, varscan2
- PTX4 | c.520C>T p.R174W (on ENST00000447419 / NM_001328608.2; = p.R169W on NM_001013658.1) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs769980908, COSV99560740; called by muse, mutect2, varscan2
- ROBO2 | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as rs762523752, COSV59925028; called by muse, mutect2, varscan2
- RYR1 | c.5038G>A p.V1680M | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161726783, COSV100616697; called by muse, mutect2, varscan2
- SCUBE1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs201101225; called by muse, mutect2, varscan2
- SNX27 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919111; called by muse, mutect2, varscan2
- TSHZ2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs779892655, COSV61589413; called by muse, mutect2, varscan2
- ZEB1 | c.506T>C p.L169S | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100314862; called by muse, mutect2, varscan2
- ZNF274 | c.403G>T p.D135Y (on ENST00000610905; = p.D30Y on NM_016324.3) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100465405; called by muse, mutect2, varscan2
- ZNF45 | c.1893_1894del p.R632Sfs*11 | Frame Shift Del (DEL) | VAF 102/647 reads (16%) | catalogued as rs770092846; called by mutect2, pindel, varscan2
- KHDRBS2 | c.471dup p.F158Ifs*5 | Frame Shift Ins (INS) | VAF 58/413 reads (14%) | called by mutect2, pindel, varscan2
- LRRK2 | c.5492_5494del p.M1831del | In Frame Del (DEL) | VAF 46/360 reads (13%) | called by pindel, varscan2
- TDP2 | c.594_599del p.F199_P200del | In Frame Del (DEL) | VAF 31/294 reads (11%) | called by mutect2, pindel, varscan2
- CACNA1I | c.5202C>T p.D1734= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs780538955, COSV100361272; called by muse, mutect2, varscan2
- MAP3K21 | c.2532A>G p.G844= | Silent (SNP) | VAF 36/364 reads (10%) | catalogued as COSV100786147; called by muse, mutect2, varscan2
- MRC1 | c.4005A>G p.L1335= | Silent (SNP) | VAF 164/1118 reads (15%) | catalogued as rs1272658233; called by muse, mutect2, varscan2
- VGLL2 | c.942C>G p.S314= (on ENST00000326274 / NM_182645.3; = p.S140= on NM_153453.1) | Silent (SNP) | VAF 165/1282 reads (13%) | catalogued as rs762066770, COSV100409989; called by muse, mutect2, varscan2
